Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V9, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V9-01A (Primary Tumor).

[page 1 of 4]
Neck
and Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:
Papillary thyroid carcinoma.

Specimens Submitted:

- 1: Total thyroidectomy
- 2: Right neck level two
- 3: Right neck level three
- 4: Right neck level four
- 5: Anterior neck fat
- 6: Central compartment neck

DIAGNOSIS:

1. Total thyroidectomy:

Part # 1

Tumor Type:

Multiple foci of papillary carcinoma: One classical type and four microcarcinomas

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Both lobes and isthmus

The largest tumor is located in the right lobe

Tumor Size:

Tumor foci range from 0.2 cm to 2.3 cm in greatest dimension.

Tumor Encapsulation:

Partially surrounded

For the largest tumor focus

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Gross foci present

1C0-0-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73A 52-12
R2

[page 2 of 4]
Non-Neoplastic Thyroid:
Exhibits chronic lymphocytic thyroiditis
Parathyroid Glands:
Not identified

2. Right neck level two, excision:
-Fifteen benign lymph nodes (0/15).

3. Right neck level three:

Part # 2

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 19
Number of lymph nodes with metastatic disease: 6
Size of the largest lymph node involved by tumor: 1.2cm.
Size of the largest metastatic focus : 0.8 cm.
Extranodal extension is not identified

4. Right neck level four:

Part # 4

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 15
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.4cm.
Size of the largest metastatic focus : 0.2 cm.
Extranodal extension is not identified

5. Anterior neck fat, biopsy:
-Fibroadipose tissue, no tumor seen.

6. Central compartment neck:

Part # 6

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 7
Number of lymph nodes with metastatic disease: 5
Size of the largest lymph node involved by tumor: 0.9cm.
Size of the largest metastatic focus : 0.7 cm.
Extranodal extension is not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 3 of 4]
1) The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid weighing 15.5 g. A stitch marks the right superior pole. The right lobe measures 4.8 x 2.5 x 1.6 cm, the left lobe measures 4.8 x 2.2 x 1.2 cm, and the isthmus measures 2.5 x 1.2 x 0.6 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals three well-circumscribed, focally calcified nodules, measuring 0.7 cm (left inferior lobe, arbitrarily designated as N1), 0.4 cm (right superior lobe, arbitrarily designated N2), and 2.3 cm (right mid-inferior lobe, arbitrarily designated N3) in greatest dimension. The isthmus displays homogeneous, beefy red cut surfaces; no discrete lesions are grossly identified. s taken. The left and right lobes and isthmus are entirely submitted sequentially from superior to inferior.

Summary of sections:

N1 - nodule 1 (0.7 cm, left inferior lobe)
N2 - nodule 2 (0.4 cm, right superior lobe)
N3 - nodule 3 (2.3 cm, right mid-inferior lobe)
RL - remaining right lobe
LL - remaining left lobe
IS - isthmus

2). The specimen is received fresh, labeled "right neck, level 2", and consists of a portion of adipose tissue measuring 4 x 2.5 x 0.6 cm. Multiple pink tan firm lymph nodes ranging from 2 to 0.2 Cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN - bisected lymph nodes
LN - lymph nodes

3). The specimen is received fresh, labeled "right neck, level 3," and consists of a portion of adipose tissue measuring 3 x 1.9 x 0.8 cm. Multiple pink tan firm lymph nodes ranging from 0.7 cm to 0.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

BLN - 2 bisected lymph nodes, one inked blue
LN - lymph nodes

4). The specimen is received fresh, labeled "right neck level 4", and consists of a 3 x 2.3 x 1 cm portion of adipose tissue. Multiple pink tan firm lymph nodes ranging from 0.6 To 0.3 Cm in greatest dimension are identified. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

5). The specimen is received fresh, labeled "anterior neck fat", and consists of a 5 x 2.5 x 0.4 cm portion of adipose tissue. No lymph nodes are grossly identified. The entire specimen is submitted.

Summary of sections:

F- entire fat

[page 4 of 4]
6). The specimen is received fresh, labeled " central compartment neck " and consists of single piece of fatty tissue measuring 4 x 2 x 0.5 cm, 4 lymph nodes are identified, they are entirely submitted.

Summary of sections:

LN--lymph nodes

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
2	IS	4
3	LL	6
2	N1	2
1	N2	3
4	N8	4
1	RL	2

Part 2: Right neck level two

Block	Sect. Site	PCs
1	BLN	2
2	LN	2

Part 3: Right neck level three

Block	Sect. Site	PCs
1	BLN	2
4	LN	4

Part 4: Right neck level four

Block	Sect. Site	PCs
5	LN	5

Part 5: Anterior neck fat

Block	Sect. Site	PCs
3	F	3

Part 6: Central compartment neck

Block	Sect. Site	PCs
1	LN	3

Source: NCI Genomic Data Commons file 66d9de41-adb9-4f3b-8c93-6179a0a7738a (TCGA-DJ-A3V9.446397DB-BAEB-4EE7-B3EA-78CECD26266C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).